Somatic mutation profile of tumor specimen TCGA-VQ-AA6J-01A (aliquot TCGA-VQ-AA6J-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6J, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 75.3 years (27,506 days).
Specimen TCGA-VQ-AA6J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e5a336d-2a52-461d-9a4d-9df7a10406fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6J-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6J-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/224bcb8e-a176-4306-9e42-647eff8bddfc

The open-access MAF lists 147 somatic variants for this specimen: 110 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 35, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908596, CM080433, COSV61068347, COSV61068483; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.880A>G p.S294G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV104413339, COSV60484790; called by muse, mutect2, varscan2
- ALX1 | c.20A>C p.K7T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57494229; called by muse, mutect2, varscan2
- ATP10A | c.3631G>A p.A1211T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs774142875, COSV63517153, COSV63518435; called by muse, mutect2, varscan2
- AVPR1A | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.531); catalogued as COSV100146787; called by muse, mutect2, varscan2
- BASP1 | c.664A>C p.T222P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100493580; called by muse, mutect2, varscan2
- BMP10 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770302; called by muse, mutect2, varscan2
- C8orf34 | c.1068A>C p.E356D | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100444858; called by muse, mutect2
- CACNA1S | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100754740; called by muse, mutect2
- CARMIL1 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs1363436569, COSV100277132; called by muse, mutect2
- CD93 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1472030449, COSV99848969; called by muse, mutect2, varscan2
- CDH12 | c.1389A>C p.K463N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66393702, COSV66402702; called by muse, mutect2, varscan2
- CDK1 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749375137, COSV100358776; called by muse, mutect2, varscan2
- CDK5RAP2 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs760376676, COSV100575184; called by muse, mutect2
- CDKN2D | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100224738; called by muse, mutect2
- CEP170 | c.1450A>C p.T484P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100316577; called by muse, mutect2, varscan2
- CFAP52 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV100234862; called by muse, mutect2, varscan2
- CFAP58 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV100458783; called by muse, mutect2, varscan2
- CNKSR2 | c.98A>C p.N33T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV54249995, COSV99667625; called by muse, mutect2, varscan2
- COL6A6 | c.866A>C p.K289T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100649947; called by muse, mutect2, varscan2
- CPNE8 | c.481T>G p.L161V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV100504031; called by muse, mutect2, varscan2
- CSMD3 | c.10797A>C p.K3599N (on ENST00000297405 / NM_001363185.1; = p.K3430N on NM_052900.3) | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV52133513, COSV99836776; called by muse, mutect2, varscan2
- CTNND2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs905114117, COSV58917426; called by muse, mutect2
- CYLC1 | c.1946A>C p.K649T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1262881184, COSV61410852; called by muse, mutect2, varscan2
- CYP4B1 | c.1205-1G>A p.X402_splice | Splice Site (SNP) | VAF 12/138 reads (9%) | catalogued as COSV99596872; called by muse, mutect2
- DNAH11 | c.3202G>A p.A1068T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100177769; called by muse, mutect2, varscan2
- DNAH5 | c.13285C>T p.R4429* | Nonsense Mutation (SNP) | VAF 58/166 reads (35%) | catalogued as COSV54229483; called by muse, mutect2, varscan2
- DOK6 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.094); catalogued as rs368072664; called by muse, varscan2
- DPYS | c.1364T>A p.V455D | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV60909953; called by muse, mutect2, varscan2
- EPHB1 | c.451T>G p.F151V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV101212774, COSV67660470; called by muse, mutect2, varscan2
- EPHB1 | c.2135A>T p.N712I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212777, COSV67667733; called by muse, mutect2, varscan2
- EPX | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99836309; called by muse, mutect2, varscan2
- ERCC3 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99573118; called by muse, mutect2, varscan2
- EVC2 | c.1349A>T p.K450M | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100185266; called by muse, mutect2, varscan2
- FAM133A | c.745T>C p.*249Qext*8 | Nonstop Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs1339444018, COSV59074665; called by muse, mutect2, varscan2
- FBXO42 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs1467463636, COSV100981668, COSV100981877; called by muse, mutect2, varscan2
- FSHR | c.236A>C p.Q79P | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as COSV58620123; called by muse, mutect2, varscan2
- GABRG1 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as rs1424400113, COSV99777545; called by muse, mutect2, varscan2
- GPR26 | c.986G>T p.S329I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99500780; called by muse, mutect2
- GRM1 | c.2801C>A p.T934N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV99264592; called by muse, mutect2, varscan2
- H4C2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1013417910, COSV55139421, COSV55141333; called by muse, mutect2, varscan2
- KALRN | c.1904A>C p.Q635P | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99562564; called by muse, mutect2, varscan2
- KCNK9 | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV57285980; called by muse, mutect2, varscan2
- KCNV1 | c.1306T>G p.F436V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV52089428; called by muse, mutect2, varscan2
- KIF2B | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52130306; called by muse, mutect2, varscan2
- LDB2 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100452788, COSV58783077; called by muse, mutect2, varscan2
- LILRB4 | c.985T>G p.F329V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99553426, COSV99553554; called by muse, mutect2, varscan2
- LIPI | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV100753482; called by muse, mutect2
- LOXL4 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs756712441, COSV99583644; called by muse, mutect2, varscan2
- LPIN2 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371146662; called by muse, mutect2, varscan2
- LRP1B | c.12600A>C p.K4200N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV101253729; called by muse, mutect2, varscan2
- MRPL28 | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99170600; called by muse, mutect2, varscan2
- MSH2 | c.2671G>A p.V891M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV99253375; called by muse, mutect2, varscan2
- NAIP | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.057); catalogued as COSV99519181; called by muse, mutect2, varscan2
- NEK11 | c.218C>G p.T73S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV100797581; called by muse, varscan2
- NEXMIF | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV50027401, COSV99279917; called by muse, mutect2, varscan2
- NID1 | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99937111; called by mutect2, varscan2
- NLRP7 | c.818G>T p.W273L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs763833424, COSV60182807; called by muse, mutect2, varscan2
- NRG3 | c.1825A>C p.T609P (on ENST00000404547 / NM_001370084.1; = p.T585P on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.439); catalogued as rs757686427; called by muse, mutect2, varscan2
- OBSCN | c.14893G>A p.D4965N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264650038, COSV99471380; called by muse, mutect2, varscan2
- OR10K1 | c.638T>G p.L213R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56872860, COSV99193934; called by muse, mutect2
- OR51D1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs529314887, COSV62914101; called by muse, mutect2, varscan2
- PAPPA | c.3358G>A p.V1120M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1392197984, COSV60289914; called by muse, mutect2
- PBX1 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100904969; called by muse, mutect2
- PCDH9 | c.558T>G p.S186R | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV100118921; called by muse, mutect2
- PCDHB7 | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1554280131, COSV50756008; called by muse, mutect2, varscan2
- PCSK2 | c.323A>T p.K108M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99358874; called by muse, mutect2
- PHIP | c.4289G>A p.R1430H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs370592424; called by muse, mutect2
- PHLPP2 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.493); catalogued as rs1043331098, COSV100673546; called by mutect2, varscan2
- PIANP | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.087); catalogued as rs1437148048, COSV100272287; called by muse, mutect2, varscan2
- PLA2G4C | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100843857; called by muse, mutect2, varscan2
- PLCL1 | c.3193A>C p.S1065R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.221); catalogued as COSV101406817; called by muse, mutect2, varscan2
- PRPH | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1345673942, COSV99141938; called by muse, mutect2, varscan2
- PTPN4 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99749701; called by muse, mutect2
- PXDN | c.2953A>C p.T985P | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99412560; called by muse, mutect2
- PXDN | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761286747, COSV99412561; called by muse, mutect2, varscan2
- RIF1 | c.3475G>A p.D1159N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV99690195; called by muse, mutect2, varscan2
- SEC11C | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as rs115898236, COSV55311471; called by muse, mutect2, varscan2
- SHOX | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.105); catalogued as rs779647794, CD013865, COSV100478829; called by muse, mutect2
- SIGLEC7 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs376908794; called by muse, mutect2, varscan2
- SLC30A8 | c.627A>C p.Q209H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV101438263; called by muse, mutect2, varscan2
- SLC44A5 | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.826); catalogued as COSV100901399, COSV63765748; called by muse, mutect2, varscan2
- SLITRK5 | c.1008A>C p.Q336H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100280420; called by muse, mutect2, varscan2
- SNTG2 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100421679; called by muse, mutect2
- SORCS2 | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs372065575; called by muse, mutect2, varscan2
- SPATA45 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs908842766, COSV100260288; called by muse, mutect2
- SPHKAP | c.1726A>T p.R576* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100763783; called by muse, mutect2, varscan2
- TAF1A | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs374979572; called by muse, mutect2, varscan2
- TLR4 | c.1593C>A p.N531K (on ENST00000355622 / NM_138554.5; = p.N491K on NM_003266.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100842682; called by muse, mutect2, varscan2
- TMC3 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.358); catalogued as COSV63924212; called by muse, mutect2
- TMEM64 | c.956T>A p.I319N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV101376011; called by muse, mutect2
- TPO | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs759194294, COSV61104908; called by muse, varscan2
- TRIM37 | c.2616G>A p.M872I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99232409; called by muse, mutect2, varscan2
- TRPC4 | c.531C>A p.N177K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV100156145, COSV59000123; called by muse, mutect2
- VCP | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as CM092555, CM117903, COSV100734134, COSV62720532; called by muse, mutect2, varscan2
- YTHDC2 | c.3690G>C p.Q1230H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV50750262, COSV99362981; called by muse, mutect2, varscan2
- ZNF100 | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV99973803; called by muse, mutect2, varscan2
- ZNF43 | c.1502A>C p.K501T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV61684853; called by muse, mutect2, varscan2
- ZNF473 | c.2279G>T p.C760F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99568562; called by muse, mutect2, varscan2
- ZNF484 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100214498; called by muse, mutect2, varscan2
- ARID1A | c.2420dup p.X807_splice | Splice Site (INS) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- CCL5 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- IGKV1-12 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2
- PRAMEF15 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.846); called by muse, mutect2
- PRAMEF15 | c.1338C>G p.D446E | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- PRAMEF19 | c.152T>G p.V51G | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- RAI2 | c.1575del p.P528Qfs*5 | Frame Shift Del (DEL) | VAF 57/206 reads (28%) | called by mutect2, pindel, varscan2
- SLC12A2 | c.582del p.H195Tfs*89 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- SLCO2A1 | c.1309del p.I437Yfs*43 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.1387del p.E463Kfs*2 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- ABCC9 | c.1875G>A p.S625= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as rs727502873, COSV99684829; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- AKAP13 | c.7200A>C p.T2400= (on ENST00000394518 / NM_007200.5; = p.T2404= on NM_006738.6) | Silent (SNP) | VAF 18/143 reads (13%) | catalogued as COSV100773218; called by muse, mutect2, varscan2
- C6 | c.114T>G p.T38= | Silent (SNP) | VAF 52/276 reads (19%) | catalogued as rs577274837, COSV99666648; called by muse, mutect2, varscan2
- CDON | c.3525C>T p.S1175= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs576546439, COSV99700778; called by muse, mutect2, varscan2
- CTNNA2 | c.577A>C p.R193= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100782120, COSV100785566; called by muse, mutect2, varscan2
- CTNNA3 | c.2289G>A p.Q763= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV101041265; called by muse, mutect2, varscan2
- DESI2 | c.30C>T p.N10= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs774875240, COSV99798002; called by muse, mutect2
- EDNRB | c.84C>T p.F28= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV57526917; called by muse, mutect2, varscan2
- ELMO3 | c.1479C>T p.H493= (on ENST00000652269; = p.H440= on NM_024712.5) | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs760145785, COSV100440688; called by muse, mutect2, varscan2
- FAM135B | c.628T>C p.L210= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1451908736, COSV52703427, COSV52706446; called by muse, mutect2, varscan2
- GPR156 | c.1524C>T p.N508= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV100251184; called by muse, mutect2, varscan2
- LIFR | c.2523C>T p.L841= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1332514427, COSV99663490; called by muse, mutect2, varscan2
- LRP8 | c.1794G>A p.L598= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100036169; called by muse, mutect2, varscan2
- MAN2A2 | c.2451G>A p.L817= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1450856807, COSV100847773; called by muse, mutect2, varscan2
- MYT1 | c.1101G>A p.S367= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs148738850; called by muse, mutect2
- NAALAD2 | c.1392G>T p.V464= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV100428131; called by muse, mutect2, varscan2
- NPAP1 | c.1977T>C p.A659= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100274672, COSV100274894; called by muse, mutect2
- NUMA1 | c.1503C>T p.A501= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as rs777949805, COSV100705875; called by muse, mutect2, varscan2
- OAS1 | c.804C>A p.L268= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99177082; called by muse, mutect2, varscan2
- OPRM1 | c.957T>C p.S319= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100000638; called by muse, mutect2, varscan2
- OR6K6 | c.249G>T p.L83= (on ENST00000368144; = p.L59= on NM_001005184.1) | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100933695; called by muse, mutect2
- PEG3 | c.4674A>G p.Q1558= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99687735; called by muse, mutect2, varscan2
- PKNOX2 | c.708A>G p.Q236= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs1194115809, COSV100020290; called by muse, mutect2, varscan2
- PSMB8 | c.255T>C p.I85= (on ENST00000374882 / NM_148919.4; = p.I81= on NM_004159.5) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100841115; called by muse, mutect2, varscan2
- PTGFR | c.195G>A p.S65= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs774495214, COSV66115013; called by muse, mutect2, varscan2
- RBPJ | c.105T>G p.A35= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100623540; called by muse, mutect2, varscan2
- RP1 | c.33C>A p.I11= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99606515; called by muse, mutect2, varscan2
- SYT13 | c.843G>T p.A281= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs542601898, COSV99194656; called by muse, mutect2, varscan2
- TCP11L1 | c.1107G>A p.E369= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV100177902; called by muse, mutect2, varscan2
- TRANK1 | c.8409G>A p.P2803= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs576110310, COSV57143611; called by muse, mutect2, varscan2
- TRPM1 | c.3132C>G p.P1044= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99855488; called by muse, mutect2, varscan2
- TTN | c.55308C>T p.S18436= (on ENST00000591111; = p.S11012= on NM_003319.4) | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as rs751255726, COSV60137559, COSV60297401; ClinVar: likely benign; called by muse, mutect2
- UNC79 | c.7593A>G p.V2531= (on ENST00000393151 / NM_001346218.2; = p.V2354= on NM_020818.5) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1400246710, COSV99826267; called by muse, mutect2, varscan2
- VIP | c.42T>C p.T14= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100923914; called by muse, mutect2, varscan2
- XKR3 | c.570A>G p.R190= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV100509154; called by muse, mutect2
- KRT18P55 | n.791G>A | RNA (SNP) | VAF 10/55 reads (18%) | catalogued as rs774134668; called by muse, mutect2, varscan2
- MIR30C2 | n.66T>A | RNA (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
